Somatic mutation profile of tumor specimen MP2PRT-PASGIC-TMP1-A (aliquot MP2PRT-PASGIC-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASGIC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (887 days).
Specimen MP2PRT-PASGIC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7cbdf3b-a478-4a7e-a9b0-f54c84150dff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGIC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGIC-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfd0c0de-2d09-4281-a8c7-f16c805c631d

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 39/273 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CASP7 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.282); catalogued as rs1482095638, COSV61881393; called by muse, varscan2
- KCNMA1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs145788902, COSV54280796; called by muse, mutect2, varscan2
- SMAD6 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 104/605 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs781279097; called by muse, mutect2, varscan2
- AC138647.1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 50/459 reads (11%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TLE7 | c.1011C>T p.H337= | Silent (SNP) | VAF 42/305 reads (14%) | catalogued as rs909707864; called by muse, mutect2, varscan2
